Somatic mutation profile of tumor specimen MMRF_1547_1_BM_CD138pos (aliquot MMRF_1547_1_BM_CD138pos_T1_KHS5U_L12836) from MMRF case MMRF_1547, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,811 days).
Specimen MMRF_1547_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ceab2e8b-153c-4a07-bf6d-34a573496e87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1547_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1547_1_PB_Whole_C2_KHS5U_L12835; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65d8969c-0db7-446f-9110-e20a1e551d9e

The open-access MAF lists 88 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 16, Intron 11, Silent 8, 5'Flank 5, RNA 5, Frame Shift Del 2, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH2 | c.2775dup p.P926Afs*14 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | catalogued as rs794728455; ClinVar: pathogenic; called by mutect2, varscan2
- TPO | c.2422del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 81/324 reads (25%) | catalogued as rs763662774, CD002725, CM032390, COSV61096238; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CEP135 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57259449; called by muse, mutect2, varscan2
- CHTF18 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as rs758707757, COSV50099923; called by muse, mutect2, varscan2
- EP300 | c.5368T>G p.C1790G | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54330947; called by muse, mutect2, varscan2
- FPGT | c.1765A>G p.M589V | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs747063121; called by muse, mutect2, varscan2
- IGLV1-44 | c.153T>A p.N51K | Missense Mutation (SNP) | VAF 141/387 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as rs570745995; called by muse, varscan2
- IGLV5-45 | c.142A>C p.N48H | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs765810608; called by muse, varscan2
- LRP2 | c.5554G>A p.G1852R | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs778738509; called by muse, mutect2, varscan2
- OR11L1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100869489; called by muse, mutect2
- RAI1 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 248/631 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755078690, COSV55391766; called by muse, mutect2, varscan2
- SEL1L3 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.969); catalogued as rs758623747; called by muse, varscan2
- SGIP1 | c.1369A>G p.T457A | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV52765979; called by muse, mutect2, varscan2
- TRPC4AP | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.038); catalogued as rs144377533; called by muse, mutect2, varscan2
- USP36 | c.340T>C p.W114R | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221764390; called by muse, mutect2, varscan2
- VIT | c.2030G>T p.R677L (on ENST00000389975 / NM_001177969.1; = p.R692L on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/419 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64898125, COSV64898374; called by muse, mutect2
- ZNF135 | c.673C>T p.H225Y (on ENST00000313434 / NM_001289401.2; = p.H237Y on NM_003436.4) | Missense Mutation (SNP) | VAF 82/380 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs778238406; called by muse, mutect2, varscan2
- ABTB2 | c.1514A>C p.Q505P | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2
- C11orf16 | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CSF2 | c.185A>G p.E62G | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DDX3X | c.522T>G p.C174W (on ENST00000399959; = p.C175W on NM_001356.5) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP11 | c.706T>A p.C236S | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.063); called by muse, mutect2
- EML6 | c.2424G>C p.K808N | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ERGIC1 | c.572T>A p.I191N | Missense Mutation (SNP) | VAF 10/332 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GPR12 | c.955T>A p.C319S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV1-40 | c.61T>A p.S21T | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- IRX5 | c.68A>C p.Y23S | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ITPR3 | c.5342A>T p.K1781M | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAGEE1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MOV10L1 | c.3392G>C p.R1131T | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHEX | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- PTPN14 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF139 | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); called by muse, mutect2
- RPL5 | c.471_474del p.N157Kfs*6 | Frame Shift Del (DEL) | VAF 26/117 reads (22%) | called by mutect2, pindel, varscan2
- SLC35A3 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- SLC35B4 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.029); called by muse, mutect2
- SLC38A2 | c.611T>G p.V204G | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAK1 | c.1046A>T p.N349I (on ENST00000327628 / NM_001349247.2; = p.N291I on NM_014965.5) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UNC13C | c.6433G>A p.E2145K | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZEB2 | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZMYM6 | c.31A>T p.K11* | Nonsense Mutation (SNP) | VAF 11/393 reads (3%) | called by muse, mutect2
- ZNF468 | c.231A>C p.Q77H | Missense Mutation (SNP) | VAF 163/425 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.276); called by muse, mutect2
- DAPK1 | c.924C>T p.S308= | Silent (SNP) | VAF 62/172 reads (36%) | catalogued as rs779853952; called by muse, mutect2, varscan2
- HMBS | c.618G>A p.L206= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- ITK | c.1344C>T p.R448= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV70065146; called by muse, mutect2, varscan2
- MKI67 | c.1887G>C p.V629= | Silent (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- RNF130 | c.123G>A p.V41= | Silent (SNP) | VAF 16/318 reads (5%) | catalogued as COSV99992553; called by muse, mutect2
- TCF20 | c.801T>C p.N267= | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, varscan2
- TMEM156 | c.690C>T p.L230= | Silent (SNP) | VAF 52/153 reads (34%) | called by muse, mutect2, varscan2
- TP73 | c.1272G>A p.L424= | Silent (SNP) | VAF 48/121 reads (40%) | called by muse, mutect2, varscan2
- ABCC13 | n.499A>G | RNA (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- AQP12A | chr2:240688980 C>T | 5'Flank (SNP) | VAF 16/411 reads (4%) | catalogued as rs868428924; called by muse, mutect2
- BMPR2 | c.*6968A>G | 3'UTR (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- CARD14 | c.2692-13C>T | Intron (SNP) | VAF 167/446 reads (37%) | called by muse, mutect2, varscan2
- CASP8 | chr2:201287189 A>G | 3'Flank (SNP) | VAF 12/262 reads (5%) | catalogued as rs1448351849, COSV51852473; called by muse, mutect2
- CRKL | c.*1312A>G | 3'UTR (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.*155T>G | 3'UTR (SNP) | VAF 11/269 reads (4%) | called by muse, mutect2
- EMX2 | chr10:117542640 T>A | 5'Flank (SNP) | VAF 104/246 reads (42%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034918 T>A | 5'Flank (SNP) | VAF 124/304 reads (41%) | called by muse, mutect2, varscan2
- GABRR1 | c.*371T>G | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- GID4 | c.*438G>A | 3'UTR (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- GNAS | c.2068+667C>T | Intron (SNP) | VAF 26/81 reads (32%) | catalogued as rs1199826178; called by muse, mutect2, varscan2
- IGLL5 | chr22:22887802 T>C | 5'Flank (SNP) | VAF 27/43 reads (63%) | called by muse, mutect2, varscan2
- LINC02872 | n.2894A>G | RNA (SNP) | VAF 39/143 reads (27%) | called by muse, mutect2, varscan2
- MFSD1 | chr3:158802020 G>C | 5'Flank (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- MIR519A1 | n.29G>A | RNA (SNP) | VAF 44/165 reads (27%) | catalogued as rs191444009; called by muse, mutect2, varscan2
- MRPL19 | c.*2383G>T | 3'UTR (SNP) | VAF 45/117 reads (38%) | called by muse, mutect2, varscan2
- MTPN | c.*199A>T | 3'UTR (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- MXRA5Y | n.7482C>A | RNA (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- NRG3 | c.824-125875G>C | Intron (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- OSBP2 | c.645-9526G>A | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as rs1221037991; called by muse, mutect2, varscan2
- PCDH15 | c.*228C>T | 3'UTR (SNP) | VAF 37/82 reads (45%) | catalogued as rs1324077980; called by muse, mutect2, varscan2
- PLCB4 | c.*804A>C | 3'UTR (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- PTAR1 | c.*1207A>G | 3'UTR (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.-11+25A>C | Intron (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- RPL6 | c.715-148G>A | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- SENP1 | c.*743C>T | 3'UTR (SNP) | VAF 51/141 reads (36%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.1281-96T>A | Intron (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- SNCG | c.363+37T>C | Intron (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2
- SOCS2 | c.139+570A>T | Intron (SNP) | VAF 45/189 reads (24%) | called by muse, mutect2, varscan2
- ST7L | c.205+620T>C | Intron (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- STAG1 | c.*1360T>A | 3'UTR (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- SUB1 | c.*2744T>G | 3'UTR (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
- TMC5 | c.2440-81T>A | Intron (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- TNRC18P2 | n.2044C>T | RNA (SNP) | VAF 6/20 reads (30%) | catalogued as rs181048722; called by muse, mutect2, varscan2
- VSIR | c.*3383T>A | 3'UTR (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- XPA | c.*312A>T | 3'UTR (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- ZC3HAV1 | c.*2923T>G | 3'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
